Surgical pathology report (de-identified scan), TCGA case TCGA-V1-A9Z8, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of California San Francisco, specimen TCGA-V1-A9Z8-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

FINAL PATHOLOGIC DIAGNOSIS

ICD-O-3
Adenocarcinoma NOS 8140/3
Site: Prostate NOS C61.9
JW 11/23/14

- A. Bladder neck, biopsy: Benign prostatic tissue, no tumor.
- B. Anterior prostatic fat, radical prostatectomy: Benign fibroadipose tissue, no tumor.
- C. Lymph nodes, right pelvic, dissection: No tumor in eleven lymph nodes (0/11).
- D. Lymph nodes, left pelvic, dissection: No tumor in seven lymph nodes (0/7).
- E. Prostate gland, bilateral seminal vesicles, radical prostatectomy:
- 1. Prostatic adenocarcinoma, Gleason score 5+4 = 9, with extensive extraprostatic extension and bladder neck invasion, present at inked margin; see comment.
- 2. Prostatic adenocarcinoma in left seminal vesicle; right seminal vesicle no tumor.

COMMENT:

Synoptic Comment for Prostate Tumors

- **Type of tumor:** Small acinar adenocarcinoma.
- **Location of tumor:** Single very large high-grade tumor predominantly in anterior bilaterally from apex to base, with extension into posterior areas of prostate as well.
- **Estimated volume of tumor:** 36 cc.
- **Gleason score:** 5+4; primary pattern 5, secondary pattern 4.
- **Estimated volume > Gleason pattern 3:** 90%.
- **Involvement of capsule:** Tumor invades capsule.
- **Extraprostatic extension:** Present, extensive in multiple locations: Left anterior apex (slide E2), left and right anterior base (slides E6, E15, E17), left posterolateral base and mid gland (slides E11, E12, E19), and extensive bladder neck invasion Slides E16,17).
- **Margin status for tumor:** Positive, present extensively at anterior margin in midline from apex to base, Gleason pattern 5 (4 x 1.5 cm) in slides E1, E3-E6, E13, E17.
- **Margin status for benign prostate glands:** Benign glands at inked margins; bladder margin bilaterally (slides E16 and E17), including additional biopsy (Part A).
-

[page 2 of 3]
- **High-grade prostatic intraepithelial neoplasia (HGPIN):** None.
- **Tumor involvement of seminal vesicle:** Present; left side.
- **Perineural infiltration:** Present.
- **Lymph node status:** Negative; however, areas suspicious for lymphatic invasion are seen (slide E19).
- Total number of nodes examined: 18
- **AJCC/UICC stage:** pT4N0.

Specimen(s) Received

A: Bladder neck tissue (FS)
B: Anterior prostatic fat
C: Right pelvic lymph nodes
D: Left pelvic lymph nodes
E: Prostate and seminal vesicles (fresh)

Intraoperative Diagnosis

FS1 (A) Bladder neck, biopsy: No definite carcinoma, extensive cautery artifact present of glandular epithelium limits interpretation. ([REDACTED])

Clinical History

OR Room and Phone # (frozen specimen : intraoperative consults only): [REDACTED]
Collection Date: [REDACTED]
Collection Time: [REDACTED]
Relevant History: [REDACTED]

The patient is a [REDACTED]-year-old man. According to [REDACTED], he undergoes laparoscopic prostatectomy and bilateral pelvic lymph node dissection. The patient has a history of Gleason 5+5 prostate cancer. Elevated PSA ([REDACTED]) prompted a needle core biopsy ([REDACTED]), which revealed prostatic adenocarcinoma in all cores with Gleason scores from 4+3=7 to 5+5=10, with perineural invasion seen at the left base. Bone scan in [REDACTED] is negative for metastatic disease.

Gross Description

The case is received in five parts, labeled with the patient's name and medical record number.

Part A is received fresh and additionally labeled "bladder neck tissue," and consists of a single soft irregular piece of cauterized pink-red tissue (1 x 0.4 x 0.2 cm). The entire specimen is frozen for frozen section diagnosis 1, and subsequently submitted in cassette A1.

Part B is received in formalin and additionally labeled "anterior prostatic fat," and consists of an irregular piece of lobulated yellow-tan fatty tissue (3.3 x 2.7 x 0.8 cm), which is entirely submitted in cassettes B1-B2.

Part C is received in formalin and additionally labeled "right pelvic lymph node," and consists of multiple irregular fragments of soft, lobulated, yellow-brown fibrofatty tissue (4.7 x 4.2 x 1.5 cm). Seven rubbery-firm, yellow-tan lymph nodes (0.4 x 0.3 x 0.2 cm to 2.6 x x 0.6 cm) are identified. The entire specimen is submitted in cassettes as follows:

- C1: Four lymph nodes.
- C2: Two bisected lymph nodes (one inked blue).
- C3: One bisected lymph node.
- C4-C6: Remaining fibrofatty tissue.

Part D is received in formalin and additionally labeled "left pelvic lymph nodes," and consists of fragments of soft yellow-brown, lobulated, fatty tissue and fibrofatty tissue (5 x 4.2 x 1.3 cm). Three rubbery-firm, yellow-tan lymph nodes (0.7 x 0.5 x 0.3 cm to 4.5 x 1.5 x 0.9 cm) are identified. The entire specimen is submitted in cassettes as follows:

[page 3 of 3]
D1: Two lymph nodes.
D2-D3: One multiply sectioned lymph node.
D4-D6: Remaining fibrofatty tissue.

Part E is received fresh and additionally labeled "prostate and seminal vesicles fresh," and consists of a asymmetric prostate gland (48.5 gm; 4.2 cm apex to base x 5.2 cm width x 4 cm anterior to posterior) and attached seminal vesicle/vas deferens bundles (right 4.1 x 2.5 x 0.6 cm and left 3.7 x 2.4 x 0.5 cm).

GROSS ABNORMALITIES: A well-defined mass is not identified. However, an ill-defined, firm, light tan expansion of the anterior prostatic tissue is present in slices 1-6. The anterior fibrous stroma is open; the remaining capsule is intact. The remaining prostatic parenchyma is firm and pink-tan. The seminal vesicles are firm and gray-tan.

ORIENTED BY: Anatomic landmarks; seminal vesicles, urethra.

INKING: Anterior right - green, anterior left - blue, posterior - black.

POTENTIAL STUDIES: Snap-frozen.

TOTAL NUMBER OF SLICES (not including apex and base margin slices): 9.

AVERAGE SLICE THICKNESS: 0.4 cm.

CASSETTES: Representative sections are submitted:

Apical margin - entirely submitted, perpendicular sections.

E1: Right.

E2: Left.

Transverse section

E3: Slice 1.

Right anterior quadrant

E4: Slice 3.

E5: Slice 5.

E6: Slice 7.

Right posterior quadrant

E7: Slice 3.

E8: Slice 5.

E9: Slice 7.

Left posterior quadrant

E10: Slice 3.

E11: Slice 5.

E12: Slice 7.

Left anterior quadrant

E13: Slice 3.

E14: Slice 5.

E15: Slice 7.

Bladder margin - entirely submitted, perpendicular sections.

E16: Right.

E17: Left.

Prostatic/seminal vesicle junction and cross-section of vas deferens margin.

E18: Right.

E19: Left.

For properly consented patients, sections of the prostate not required by Pathology for diagnosis, and not submitted as described above, have been submitted to the and can also be made available. for processing

Diagnosis based on gross and microscopic examinations. Final diagnosis made by attending pathologist following review of all pathology slides. The attending pathologist has reviewed all dictations, including prosector work, and preliminary interpretations performed by any resident involved in the case and performed all necessary edits before signing the final report.

Electronically signed out on 1/8/14

Source: NCI Genomic Data Commons file 1b017707-ea1a-43aa-9ff4-96bb1e3af78a (TCGA-V1-A9Z8.3C543195-4F88-4FA4-A397-EDF375FCE61A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).